Somatic mutation profile of tumor specimen 0DOJXU from CCDI case PBCCMA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Myofibroblastic tumor, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 14.3 years (5,230 days).
Specimen 0DOJXU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 696a875d-0c0b-4d58-98eb-ccc920db2f0b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOJUW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93da3717-67ba-4ed3-bcee-5cd5f573adca

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP3B1 | c.853G>T p.D285Y | Missense Mutation (SNP) | VAF 23/747 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as COSV54885102; called by muse, mutect2
- HEPHL1 | c.1072C>G p.L358V | Missense Mutation (SNP) | VAF 44/446 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV100243911; called by muse, mutect2
- SDK2 | c.2632G>A p.G878R | Missense Mutation (SNP) | VAF 43/409 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
